Somatic mutation profile of tumor specimen TCGA-LP-A5U2-01A (aliquot TCGA-LP-A5U2-01A-11D-A28B-09) from TCGA case TCGA-LP-A5U2, project TCGA-CESC (Cervical Squamous Cell Carcinoma and Endocervical Adenocarcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Adenocarcinoma, endocervical type; Tissue or organ of origin: Cervix uteri; FIGO stage: Stage IIIB; Tumor grade: G3; Age at diagnosis: 30.3 years (11,049 days).
Specimen TCGA-LP-A5U2-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 92bf630e-c1bd-461e-8b30-47610cd9a6a0.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-LP-A5U2-10A (Blood Derived Normal), aliquot TCGA-LP-A5U2-10A-01D-A28E-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/3cd921d2-286b-4be7-ba48-0cbd22ce5c10

The open-access MAF lists 214 somatic variants for this specimen: 162 protein-altering or splice-affecting, 46 silent, 6 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 145, Silent 46, Nonsense Mutation 12, Intron 3, Splice Region 2, Splice Site 2, 3'UTR 1, 5'UTR 1, Translation Start Site 1, RNA 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.713G>T p.C238F | Missense Mutation (SNP) | VAF 26/85 reads (31%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs730882005, CM034930, COSV52661646, COSV52706816, COSV52804264; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- ABITRAM | c.357G>C p.L119F | Missense Mutation (SNP) | VAF 10/20 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV57705028; called by muse, mutect2
- AC093155.3 | c.790C>G p.H264D | Missense Mutation (SNP) | VAF 12/87 reads (14%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.006); catalogued as COSV63350026, COSV63352318; called by muse, mutect2, varscan2
- ACSF2 | c.478G>A p.A160T | Missense Mutation (SNP) | VAF 13/38 reads (34%) | SIFT tolerated (0.66); PolyPhen benign (0.042); catalogued as COSV51973908; called by muse, mutect2, varscan2
- ADAM30 | c.529G>C p.D177H | Missense Mutation (SNP) | VAF 43/63 reads (68%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.805); catalogued as COSV65561916; called by muse, mutect2, varscan2
- ADAMTS16 | c.578G>A p.R193K | Missense Mutation (SNP) | VAF 8/18 reads (44%) | SIFT tolerated (0.34); PolyPhen benign (0.026); catalogued as COSV56979593, COSV57003726; called by muse, mutect2, varscan2
- ADGRV1 | c.7942G>A p.E2648K | Missense Mutation (SNP) | VAF 21/45 reads (47%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.98); catalogued as COSV67987657; called by muse, mutect2, varscan2
- ADIRF | c.65C>T p.S22L | Missense Mutation (SNP) | VAF 12/18 reads (67%) | SIFT deleterious (0.02); PolyPhen benign (0.027); catalogued as rs143202580; called by muse, mutect2, varscan2
- ADRA1D | c.1654G>C p.E552Q | Missense Mutation (SNP) | VAF 36/98 reads (37%) | SIFT deleterious, low confidence (0.05); PolyPhen possibly damaging (0.737); catalogued as COSV65240572, COSV65241755; called by muse, mutect2, varscan2
- ALG8 | c.174G>A p.E58= | Splice Region (SNP) | VAF 30/82 reads (37%) | catalogued as rs1322707059, COSV100220071, COSV55202449; called by muse, mutect2, varscan2
- ANAPC2 | c.486C>G p.F162L | Missense Mutation (SNP) | VAF 19/34 reads (56%) | SIFT tolerated (0.75); PolyPhen benign (0.003); catalogued as COSV58808787; called by muse, mutect2, varscan2
- ANK3 | c.10657G>A p.E3553K | Missense Mutation (SNP) | VAF 11/28 reads (39%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.04); catalogued as rs376597004; called by muse, mutect2, varscan2
- AP2B1 | c.1855C>T p.Q619* | Nonsense Mutation (SNP) | VAF 24/71 reads (34%) | catalogued as COSV52002450, COSV99251602; called by muse, mutect2, varscan2
- ATP10B | c.2065G>A p.D689N | Missense Mutation (SNP) | VAF 15/38 reads (39%) | SIFT tolerated (0.13); PolyPhen benign (0.27); catalogued as rs763114091, COSV59144351, COSV59164448; called by muse, mutect2, varscan2
- ATP7A | c.1397C>T p.S466L | Missense Mutation (SNP) | VAF 5/20 reads (25%) | SIFT tolerated (0.17); PolyPhen benign (0.003); catalogued as COSV58452065; called by muse, mutect2
- BIVM-ERCC5 | c.430G>C p.D144H | Missense Mutation (SNP) | VAF 7/17 reads (41%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as COSV57282108; called by muse, mutect2, varscan2
- BRS3 | c.884C>G p.S295* | Nonsense Mutation (SNP) | VAF 21/49 reads (43%) | catalogued as COSV65711235; called by muse, mutect2, varscan2
- BTLA | c.287C>T p.S96L | Missense Mutation (SNP) | VAF 25/58 reads (43%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.994); catalogued as COSV57939937; called by muse, mutect2, varscan2
- CACHD1 | c.3443G>A p.R1148K | Missense Mutation (SNP) | VAF 33/39 reads (85%) | SIFT tolerated (0.9); PolyPhen possibly damaging (0.815); catalogued as rs1159461111, COSV51558797; called by muse, mutect2, varscan2
- CACNA1C | c.1945C>T p.R649C | Missense Mutation (SNP) | VAF 32/117 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.817); catalogued as rs769236083, COSV59710215; called by muse, mutect2, varscan2
- CBARP | c.673C>G p.L225V (on ENST00000382477; = p.L205V on NM_152769.3) | Missense Mutation (SNP) | VAF 50/94 reads (53%) | SIFT tolerated (0.17); PolyPhen benign (0.391); catalogued as COSV53071220; called by muse, mutect2, varscan2
- CC2D2A | c.4400C>G p.S1467* | Nonsense Mutation (SNP) | VAF 6/29 reads (21%) | catalogued as COSV67505315; called by muse, mutect2, varscan2
- CCAR1 | c.790C>T p.Q264* | Nonsense Mutation (SNP) | VAF 27/65 reads (42%) | catalogued as COSV56273419; called by muse, mutect2, varscan2
- CCDC144A | c.3178C>T p.H1060Y | Missense Mutation (SNP) | VAF 28/67 reads (42%) | SIFT tolerated (0.17); PolyPhen benign (0.035); catalogued as COSV60701051; called by muse, mutect2, varscan2
- CCDC153 | c.322G>A p.E108K | Missense Mutation (SNP) | VAF 14/41 reads (34%) | SIFT tolerated (0.35); PolyPhen benign (0.074); catalogued as rs759207864, COSV59541392; called by muse, mutect2, varscan2
- CCDC3 | c.482C>G p.S161* | Nonsense Mutation (SNP) | VAF 17/59 reads (29%) | catalogued as COSV66561410; called by muse, mutect2, varscan2
- CCDC33 | c.2036C>T p.S679L | Missense Mutation (SNP) | VAF 28/64 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV51434338; called by muse, mutect2, varscan2
- CCDC42 | c.826G>A p.E276K | Missense Mutation (SNP) | VAF 22/48 reads (46%) | SIFT tolerated (0.39); PolyPhen benign (0.058); catalogued as COSV53448717, COSV53449860; called by muse, mutect2, varscan2
- CCNL1 | c.1552C>G p.R518G | Missense Mutation (SNP) | VAF 19/47 reads (40%) | SIFT deleterious (0.05); PolyPhen benign (0.09); catalogued as COSV55820246; called by muse, mutect2, varscan2
- CDH17 | c.771C>G p.I257M | Missense Mutation (SNP) | VAF 9/19 reads (47%) | SIFT tolerated (0.42); PolyPhen benign (0.052); catalogued as COSV50337484; called by muse, mutect2, varscan2
- CDX4 | c.850G>A p.E284K | Missense Mutation (SNP) | VAF 8/24 reads (33%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.97); catalogued as rs758968054, COSV65171481; called by muse, mutect2, varscan2
- CEACAM20 | c.1727C>G p.S576* | Nonsense Mutation (SNP) | VAF 21/60 reads (35%) | catalogued as COSV57602937; called by muse, mutect2, varscan2
- CHD7 | c.2221G>A p.E741K | Missense Mutation (SNP) | VAF 7/29 reads (24%) | SIFT tolerated (0.16); PolyPhen benign (0.021); catalogued as COSV71113697; called by muse, mutect2, varscan2
- CHD7 | c.4205G>C p.R1402T | Missense Mutation (SNP) | VAF 6/26 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV71113701; called by muse, mutect2, varscan2
- CHD7 | c.4432G>A p.E1478K | Missense Mutation (SNP) | VAF 14/31 reads (45%) | SIFT deleterious (0); PolyPhen benign (0.324); catalogued as COSV71113706; called by muse, mutect2, varscan2
- CIT | c.913G>A p.E305K | Missense Mutation (SNP) | VAF 12/38 reads (32%) | SIFT tolerated (0.14); PolyPhen benign (0.087); catalogued as COSV55879818; called by muse, varscan2
- CLEC3B | c.247C>G p.L83V | Missense Mutation (SNP) | VAF 25/51 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV56109841, COSV56110369; called by muse, mutect2, varscan2
- CNKSR3 | c.1257G>A p.M419I | Missense Mutation (SNP) | VAF 6/15 reads (40%) | SIFT tolerated (0.1); PolyPhen benign (0.136); catalogued as COSV70481483; called by muse, mutect2, varscan2
- CNNM2 | c.1401C>G p.F467L | Missense Mutation (SNP) | VAF 22/53 reads (42%) | SIFT deleterious (0); PolyPhen benign (0.141); catalogued as COSV63996373; called by muse, mutect2, varscan2
- CNTN4 | c.2176G>A p.E726K | Missense Mutation (SNP) | VAF 20/48 reads (42%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.78); catalogued as COSV61870303; called by muse, mutect2
- CPA6 | c.470C>T p.S157L | Missense Mutation (SNP) | VAF 19/40 reads (48%) | SIFT deleterious (0); PolyPhen possibly damaging (0.724); catalogued as COSV52731732; called by muse, mutect2, varscan2
- CTIF | c.577G>C p.D193H | Missense Mutation (SNP) | VAF 33/38 reads (87%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); catalogued as COSV56490121; called by muse, mutect2, varscan2
- DEF6 | c.677G>A p.R226Q | Missense Mutation (SNP) | VAF 15/46 reads (33%) | SIFT deleterious (0); PolyPhen benign (0.278); catalogued as rs1174960430, COSV57355105; called by muse, mutect2, varscan2
- DNAJC21 | c.70C>G p.R24G | Missense Mutation (SNP) | VAF 20/62 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV57762219; called by muse, mutect2, varscan2
- DOCK11 | c.3155C>T p.S1052F | Missense Mutation (SNP) | VAF 22/67 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.862); catalogued as COSV52245999; called by muse, mutect2, varscan2
- DONSON | c.1394G>C p.R465T | Missense Mutation (SNP) | VAF 20/63 reads (32%) | SIFT deleterious (0.02); PolyPhen benign (0.02); catalogued as rs1569074441, COSV51668328; called by muse, mutect2, varscan2
- DUS3L | c.1233G>A p.M411I | Missense Mutation (SNP) | VAF 35/160 reads (22%) | SIFT deleterious (0); PolyPhen benign (0.056); catalogued as COSV57833279; called by muse, mutect2, varscan2
- EMSY | c.1344C>G p.I448M | Missense Mutation (SNP) | VAF 21/55 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV58264926; called by muse, mutect2, varscan2
- EP300 | c.2855C>G p.S952* | Nonsense Mutation (SNP) | VAF 14/56 reads (25%) | catalogued as COSV54329736, COSV99608957; called by muse, mutect2, varscan2
- EP300 | c.3807-1G>C p.X1269_splice | Splice Site (SNP) | VAF 26/42 reads (62%) | catalogued as COSV54342386; called by muse, mutect2, varscan2
- EPB41 | c.1969G>A p.E657K (on ENST00000343067 / NM_001166005.2; = p.E415K on NM_004437.4) | Missense Mutation (SNP) | VAF 11/93 reads (12%) | SIFT deleterious (0.01); PolyPhen benign (0.097); catalogued as COSV58052536; called by muse, mutect2, varscan2
- EPHX3 | c.182G>A p.S61N | Missense Mutation (SNP) | VAF 10/16 reads (63%) | SIFT tolerated (0.42); PolyPhen benign (0.001); catalogued as COSV54592866; called by mutect2, varscan2
- FBXO33 | c.818C>G p.S273C | Missense Mutation (SNP) | VAF 16/19 reads (84%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.498); catalogued as rs904377528, COSV53235611; called by muse, mutect2, varscan2
- FDPS | c.816C>G p.F272L | Missense Mutation (SNP) | VAF 16/113 reads (14%) | SIFT deleterious (0.02); PolyPhen benign (0.354); catalogued as COSV63114848; called by muse, mutect2, varscan2
- FNDC3A | c.2602G>A p.E868K (on ENST00000492622 / NM_001079673.2; = p.E812K on NM_014923.5) | Missense Mutation (SNP) | VAF 12/24 reads (50%) | SIFT tolerated (0.69); PolyPhen benign (0.101); catalogued as COSV68134588; called by muse, mutect2, varscan2
- FPR3 | c.1000A>G p.T334A | Missense Mutation (SNP) | VAF 19/35 reads (54%) | SIFT tolerated (0.21); PolyPhen benign (0.024); catalogued as COSV59331596; called by muse, mutect2, varscan2
- FRAS1 | c.3889G>C p.D1297H | Missense Mutation (SNP) | VAF 7/19 reads (37%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.717); catalogued as rs1396358890, COSV53638910; called by muse, mutect2, varscan2
- GLUD1 | c.947C>G p.S316C | Missense Mutation (SNP) | VAF 19/35 reads (54%) | SIFT tolerated (0.09); PolyPhen benign (0.063); catalogued as COSV53280733; called by muse, mutect2, varscan2
- GNA11 | c.721G>A p.E241K | Missense Mutation (SNP) | VAF 53/79 reads (67%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.987); catalogued as COSV99313184; called by muse, mutect2, varscan2
- GNE | c.487C>T p.H163Y (on ENST00000396594 / NM_001128227.3; = p.H132Y on NM_005476.7 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 28/52 reads (54%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV64952758; called by muse, mutect2, varscan2
- GSTM4 | c.77C>G p.S26* | Nonsense Mutation (SNP) | VAF 40/53 reads (75%) | catalogued as COSV58695971; called by muse, mutect2, varscan2
- HAP1 | c.955G>A p.E319K | Missense Mutation (SNP) | VAF 7/24 reads (29%) | SIFT tolerated (0.42); PolyPhen benign (0.023); catalogued as COSV57880281; called by muse, mutect2, varscan2
- HSD17B4 | c.1409T>C p.V470A (on ENST00000414835 / NM_001199291.3; = p.V445A on NM_000414.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 6/27 reads (22%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.716); catalogued as COSV56338555; called by muse, mutect2, varscan2
- HSPA4 | c.1633G>C p.E545Q | Missense Mutation (SNP) | VAF 18/39 reads (46%) | SIFT tolerated (0.27); PolyPhen benign (0.214); catalogued as COSV59183391; called by muse, mutect2, varscan2
- IFNGR1 | c.439C>T p.H147Y | Missense Mutation (SNP) | VAF 23/48 reads (48%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.731); catalogued as COSV62990222; called by muse, mutect2, varscan2
- IFNL2 | c.563G>T p.R188L | Missense Mutation (SNP) | VAF 33/94 reads (35%) | SIFT deleterious (0.04); PolyPhen benign (0.017); catalogued as COSV59593442, COSV59594033; called by muse, mutect2, varscan2
- IFT172 | c.3217G>C p.E1073Q | Missense Mutation (SNP) | VAF 46/126 reads (37%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.917); catalogued as COSV53138006; called by muse, mutect2, varscan2
- IGSF9 | c.3050C>T p.P1017L (on ENST00000368094 / NM_001135050.2; = p.P1001L on NM_020789.4) | Missense Mutation (SNP) | VAF 14/20 reads (70%) | SIFT deleterious (0.01); PolyPhen benign (0.321); catalogued as COSV57423418; called by muse, mutect2, varscan2
- KCNA4 | c.1708G>C p.E570Q | Missense Mutation (SNP) | VAF 23/41 reads (56%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.979); catalogued as rs1331603271, COSV60251407, COSV60255287; called by muse, mutect2, varscan2
- KDM4B | c.584T>A p.L195Q | Missense Mutation (SNP) | VAF 27/72 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV50248730; called by muse, mutect2, varscan2
- KIAA1210 | c.839G>C p.G280A | Missense Mutation (SNP) | VAF 17/44 reads (39%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.51); catalogued as COSV68179470; called by muse, mutect2, varscan2
- KIF4B | c.3671C>G p.S1224C | Missense Mutation (SNP) | VAF 19/43 reads (44%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); catalogued as COSV70530978; called by muse, mutect2, varscan2
- KLHL18 | c.1244C>T p.S415L | Missense Mutation (SNP) | VAF 33/72 reads (46%) | SIFT deleterious (0.01); PolyPhen benign (0.347); catalogued as rs748872849, COSV51748112; called by muse, mutect2, varscan2
- KMT2D | c.3085C>T p.Q1029* | Nonsense Mutation (SNP) | VAF 18/36 reads (50%) | catalogued as COSV56416293; called by muse, mutect2, varscan2
- LCAT | c.1099G>C p.D367H | Missense Mutation (SNP) | VAF 29/51 reads (57%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV50454526; called by muse, mutect2, varscan2
- LRP5 | c.4600C>G p.R1534G | Missense Mutation (SNP) | VAF 25/56 reads (45%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.944); catalogued as rs149645175, CM053970, COSV53713906; called by muse, mutect2, varscan2
- LRRK1 | c.5425G>C p.E1809Q | Missense Mutation (SNP) | VAF 5/25 reads (20%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.007); catalogued as rs749480379, COSV52623894; called by muse, mutect2, varscan2
- LUM | c.118G>A p.E40K | Missense Mutation (SNP) | VAF 20/81 reads (25%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.949); catalogued as COSV57128985; called by muse, mutect2, varscan2
- LYPD3 | c.212-2A>G p.X71_splice | Splice Site (SNP) | VAF 19/76 reads (25%) | catalogued as rs768331527, COSV54989507; called by muse, mutect2, varscan2
- LYPD5 | c.376G>A p.D126N (on ENST00000377950 / NM_001031749.3; = p.D83N on NM_182573.2) | Missense Mutation (SNP) | VAF 60/116 reads (52%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs747282478, COSV65021146; called by muse, mutect2, varscan2
- MAB21L1 | c.807G>C p.L269F | Missense Mutation (SNP) | VAF 15/28 reads (54%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.9); catalogued as COSV59814833; called by muse, mutect2, varscan2
- MAOB | c.256G>A p.E86K | Missense Mutation (SNP) | VAF 12/30 reads (40%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.806); catalogued as COSV65204488; called by muse, mutect2, varscan2
- MAP6D1 | c.360C>G p.I120M | Missense Mutation (SNP) | VAF 5/11 reads (45%) | SIFT tolerated (0.22); PolyPhen possibly damaging (0.476); catalogued as COSV57701961; called by muse, mutect2, varscan2
- MBD5 | c.3727G>A p.E1243K | Missense Mutation (SNP) | VAF 9/27 reads (33%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0.006); catalogued as rs868827314, COSV68698683; called by muse, mutect2, varscan2
- MBLAC1 | c.316G>C p.D106H | Missense Mutation (SNP) | VAF 24/61 reads (39%) | SIFT deleterious (0.02); PolyPhen benign (0.059); catalogued as COSV53543172; called by muse, mutect2, varscan2
- MED1 | c.1597G>C p.E533Q | Missense Mutation (SNP) | VAF 12/34 reads (35%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.979); catalogued as COSV56127912; called by muse, mutect2, varscan2
- METAP1D | c.388C>T p.R130W | Missense Mutation (SNP) | VAF 13/92 reads (14%) | SIFT deleterious (0); PolyPhen benign (0); catalogued as rs762564065, COSV59931047; called by muse, mutect2, varscan2
- MEX3B | c.202G>C p.E68Q | Missense Mutation (SNP) | VAF 14/27 reads (52%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.939); catalogued as COSV61664166; called by muse, mutect2
- MGAM | c.4078G>A p.D1360N | Missense Mutation (SNP) | VAF 84/181 reads (46%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV72075414; called by muse, mutect2, varscan2
- MROH2B | c.3614C>G p.S1205* | Nonsense Mutation (SNP) | VAF 25/68 reads (37%) | catalogued as COSV101270952, COSV68188380; called by muse, mutect2, varscan2
- MSH4 | c.997C>G p.H333D | Missense Mutation (SNP) | VAF 11/37 reads (30%) | SIFT tolerated (0.11); PolyPhen benign (0.191); catalogued as COSV54209898; called by muse, mutect2, varscan2
- MTHFD1L | c.2914G>C p.E972Q | Missense Mutation (SNP) | VAF 15/34 reads (44%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.998); catalogued as COSV66226982; called by muse, mutect2, varscan2
- MTNR1B | c.528C>A p.F176L | Missense Mutation (SNP) | VAF 13/55 reads (24%) | SIFT tolerated (0.51); PolyPhen benign (0.075); catalogued as COSV57068279; called by muse, mutect2, varscan2
- MUC17 | c.3349G>A p.E1117K | Missense Mutation (SNP) | VAF 34/90 reads (38%) | SIFT deleterious (0.04); PolyPhen benign (0.19); catalogued as COSV60300190; called by muse, mutect2, varscan2
- MUC17 | c.4765G>C p.E1589Q | Missense Mutation (SNP) | VAF 21/65 reads (32%) | SIFT deleterious (0.04); PolyPhen benign (0.093); catalogued as COSV60300198; called by muse, mutect2, varscan2
- MYH14 | c.5281G>C p.E1761Q | Missense Mutation (SNP) | VAF 17/56 reads (30%) | SIFT tolerated (0.13); PolyPhen probably damaging (1); catalogued as COSV51828675; called by muse, mutect2, varscan2
- NAT10 | c.1757C>T p.S586F | Missense Mutation (SNP) | VAF 49/119 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV57665813; called by muse, mutect2, varscan2
- NBEAL1 | c.6609G>C p.R2203S | Missense Mutation (SNP) | VAF 17/32 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV68917055; called by muse, mutect2, varscan2
- NEB | c.12221C>A p.A4074D | Missense Mutation (SNP) | VAF 7/63 reads (11%) | SIFT tolerated (0.26); PolyPhen benign (0.274); catalogued as COSV51450629; called by muse, mutect2, varscan2
- NLRP6 | c.1051G>T p.D351Y | Missense Mutation (SNP) | VAF 10/20 reads (50%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.975); catalogued as COSV100381260, COSV56461681; called by muse, mutect2, varscan2
- NMT2 | c.395A>C p.E132A | Missense Mutation (SNP) | VAF 10/40 reads (25%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.838); catalogued as COSV65383025; called by muse, mutect2, varscan2
- NPTX1 | c.511G>A p.D171N | Missense Mutation (SNP) | VAF 61/95 reads (64%) | SIFT tolerated (0.24); PolyPhen possibly damaging (0.734); catalogued as COSV100151202, COSV60774327, COSV60776207; called by muse, mutect2, varscan2
- NUP153 | c.3896C>G p.S1299C | Missense Mutation (SNP) | VAF 20/42 reads (48%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.694); catalogued as rs775294839, COSV50460512; called by muse, mutect2, varscan2
- OLA1 | c.634G>A p.E212K | Missense Mutation (SNP) | VAF 13/41 reads (32%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.841); catalogued as COSV52973339; called by muse, mutect2, varscan2
- OR51V1 | c.565C>T p.R189C | Missense Mutation (SNP) | VAF 8/22 reads (36%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.988); catalogued as rs151191536; called by muse, mutect2, varscan2
- PANX2 | c.508G>C p.E170Q | Missense Mutation (SNP) | VAF 21/54 reads (39%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.998); catalogued as rs1485043074, COSV50293248, COSV50308756; called by muse, mutect2, varscan2
- PCBD2 | c.183C>G p.I61M | Missense Mutation (SNP) | VAF 26/45 reads (58%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.968); catalogued as COSV54738552; called by muse, mutect2, varscan2
- PCDHB2 | c.2356G>A p.E786K | Missense Mutation (SNP) | VAF 29/80 reads (36%) | SIFT tolerated, low confidence (0.17); PolyPhen benign (0.007); catalogued as rs1181323447, COSV50615862; called by muse, mutect2, varscan2
- PCDHGB6 | c.1015G>C p.D339H | Missense Mutation (SNP) | VAF 20/57 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54012163; called by muse, mutect2, varscan2
- PDE5A | c.1924G>C p.E642Q | Missense Mutation (SNP) | VAF 9/26 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV53351760; called by muse, mutect2, varscan2
- PIGX | c.235C>G p.L79V | Missense Mutation (SNP) | VAF 29/65 reads (45%) | SIFT tolerated (1); PolyPhen benign (0.011); catalogued as COSV56359607, COSV56360990; called by muse, mutect2, varscan2
- PKD2L1 | c.954G>C p.L318= | Splice Region (SNP) | VAF 5/25 reads (20%) | catalogued as COSV58396255, COSV58398270; called by muse, mutect2, varscan2
- POLR3A | c.1495G>A p.D499N | Missense Mutation (SNP) | VAF 8/23 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.965); catalogued as COSV64931862; called by muse, mutect2, varscan2
- PRG2 | c.268C>T p.P90S | Missense Mutation (SNP) | VAF 10/63 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.906); catalogued as COSV61294014; called by muse, mutect2, varscan2
- PRKG2 | c.2022G>C p.K674N | Missense Mutation (SNP) | VAF 17/54 reads (31%) | SIFT tolerated (0.35); PolyPhen benign (0.007); catalogued as COSV52330471; called by muse, mutect2, varscan2
- RASD1 | c.3G>C p.M1? | Translation Start Site (SNP) | VAF 18/38 reads (47%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.031); catalogued as COSV51958228; called by muse, mutect2, varscan2
- RGL2 | c.1783C>G p.P595A | Missense Mutation (SNP) | VAF 24/73 reads (33%) | SIFT tolerated (0.46); PolyPhen benign (0); catalogued as COSV65842855; called by muse, mutect2, varscan2
- RLN1 | c.70G>A p.A24T | Missense Mutation (SNP) | VAF 8/103 reads (8%) | SIFT tolerated (0.48); PolyPhen benign (0); catalogued as COSV99802740; called by muse, mutect2
- RNASE8 | c.142C>G p.Q48E | Missense Mutation (SNP) | VAF 24/48 reads (50%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as COSV57551839; called by muse, mutect2, varscan2
- RNF114 | c.109G>C p.E37Q | Missense Mutation (SNP) | VAF 5/17 reads (29%) | SIFT tolerated (0.25); PolyPhen possibly damaging (0.761); catalogued as COSV54870761; called by mutect2, varscan2
- RNF130 | c.449G>C p.G150A | Missense Mutation (SNP) | VAF 6/19 reads (32%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.574); catalogued as COSV56152918; called by muse, mutect2, varscan2
- RNF213 | c.7867C>G p.Q2623E | Missense Mutation (SNP) | VAF 20/73 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV60404079; called by muse, mutect2, varscan2
- SEC23IP | c.80C>T p.S27L | Missense Mutation (SNP) | VAF 32/76 reads (42%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.338); catalogued as rs774300336, COSV64832785; called by muse, mutect2, varscan2
- SEPTIN14 | c.826G>A p.E276K | Missense Mutation (SNP) | VAF 24/57 reads (42%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); catalogued as rs78957351, COSV66430367; called by muse, mutect2, varscan2
- SEZ6L | c.679G>C p.D227H | Missense Mutation (SNP) | VAF 4/16 reads (25%) | SIFT tolerated (0.11); PolyPhen benign (0.191); catalogued as rs147999138, COSV50657709, COSV50657985; called by muse, mutect2
- SLC25A15 | c.435G>C p.K145N | Missense Mutation (SNP) | VAF 28/76 reads (37%) | SIFT deleterious (0.04); PolyPhen benign (0.088); catalogued as COSV58557847; called by muse, mutect2, varscan2
- SLC25A53 | c.223C>G p.Q75E | Missense Mutation (SNP) | VAF 24/56 reads (43%) | SIFT tolerated (0.36); PolyPhen benign (0.054); catalogued as COSV62460429; called by muse, mutect2, varscan2
- SLC7A11 | c.787G>A p.E263K | Missense Mutation (SNP) | VAF 10/35 reads (29%) | SIFT tolerated (0.1); PolyPhen benign (0.101); catalogued as COSV54932798; called by muse, mutect2, varscan2
- SMARCA2 | c.3583G>C p.D1195H | Missense Mutation (SNP) | VAF 14/42 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.476); catalogued as COSV61811269; called by muse, mutect2, varscan2
- SMARCA2 | c.3940G>A p.V1314M | Missense Mutation (SNP) | VAF 4/36 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.992); catalogued as COSV61811285; called by muse, mutect2
- SMARCAD1 | c.19G>T p.D7Y | Missense Mutation (SNP) | VAF 7/22 reads (32%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.99); catalogued as COSV62775874; called by muse, mutect2
- SMPDL3B | c.765C>G p.F255L | Missense Mutation (SNP) | VAF 7/55 reads (13%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.984); catalogued as COSV65855225; called by muse, mutect2, varscan2
- SSH1 | c.892G>C p.E298Q | Missense Mutation (SNP) | VAF 18/68 reads (26%) | SIFT tolerated (0.13); PolyPhen benign (0.303); catalogued as COSV58457580, COSV58459279; called by muse, mutect2, varscan2
- STON2 | c.290C>T p.S97L | Missense Mutation (SNP) | VAF 23/37 reads (62%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.013); catalogued as rs779833553, COSV50851865; called by muse, mutect2, varscan2
- STX7 | c.727C>G p.L243V | Missense Mutation (SNP) | VAF 8/26 reads (31%) | SIFT tolerated (0.64); PolyPhen benign (0); catalogued as COSV100908416, COSV63399238; called by muse, mutect2, varscan2
- SUFU | c.409C>T p.P137S | Missense Mutation (SNP) | VAF 13/120 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1564676427, COSV64015998; ClinVar: uncertain significance; called by muse, mutect2
- SYNPO2 | c.2014G>C p.E672Q | Missense Mutation (SNP) | VAF 9/18 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV100205776, COSV61115463; called by muse, mutect2, varscan2
- TACC3 | c.2338G>T p.E780* | Nonsense Mutation (SNP) | VAF 8/26 reads (31%) | catalogued as COSV57607231; called by muse, mutect2, varscan2
- TANGO6 | c.3172G>A p.D1058N | Missense Mutation (SNP) | VAF 17/41 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs369656531; called by muse, mutect2, varscan2
- TBC1D24 | c.240G>C p.K80N | Missense Mutation (SNP) | VAF 29/60 reads (48%) | SIFT tolerated (0.23); PolyPhen benign (0.129); catalogued as COSV53548167; called by muse, mutect2, varscan2
- THADA | c.3947G>A p.R1316H | Missense Mutation (SNP) | VAF 12/39 reads (31%) | SIFT tolerated (0.06); PolyPhen benign (0.374); catalogued as rs200421057, COSV57691243; called by muse, mutect2, varscan2
- TIGD4 | c.817G>C p.D273H | Missense Mutation (SNP) | VAF 23/50 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV58550677; called by muse, mutect2, varscan2
- TNS1 | c.2710G>C p.E904Q | Missense Mutation (SNP) | VAF 49/55 reads (89%) | SIFT tolerated (0.44); PolyPhen benign (0.069); catalogued as COSV50751863; called by muse, mutect2, varscan2
- TRAP1 | c.1972C>T p.R658C | Missense Mutation (SNP) | VAF 5/18 reads (28%) | SIFT deleterious (0); PolyPhen benign (0.4); catalogued as rs139636268; called by muse, mutect2, varscan2
- TSPOAP1 | c.4793G>C p.R1598T | Missense Mutation (SNP) | VAF 10/23 reads (43%) | SIFT deleterious (0.03); PolyPhen benign (0.039); catalogued as COSV52115801, COSV99271656; called by muse, mutect2, varscan2
- TTLL3 | c.443G>A p.R148K | Missense Mutation (SNP) | VAF 13/42 reads (31%) | SIFT tolerated (0.61); PolyPhen benign (0.026); catalogued as COSV55029386; called by muse, mutect2, varscan2
- TTLL8 | c.1868C>G p.S623W | Missense Mutation (SNP) | VAF 7/12 reads (58%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.59); catalogued as COSV56728521; called by muse, mutect2, varscan2
- UBE2O | c.2962C>G p.L988V | Missense Mutation (SNP) | VAF 28/55 reads (51%) | SIFT tolerated (0.61); PolyPhen possibly damaging (0.88); catalogued as COSV60066817; called by muse, mutect2, varscan2
- UQCRQ | c.202G>C p.E68Q | Missense Mutation (SNP) | VAF 10/29 reads (34%) | SIFT tolerated (0.19); PolyPhen benign (0.262); catalogued as COSV51526984; called by muse, mutect2, varscan2
- USP24 | c.1178G>A p.R393H | Missense Mutation (SNP) | VAF 19/49 reads (39%) | SIFT deleterious (0); PolyPhen possibly damaging (0.57); catalogued as rs567412757, COSV53776148; called by muse, mutect2, varscan2
- UTP20 | c.6029G>C p.G2010A | Missense Mutation (SNP) | VAF 21/51 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV55383796; called by muse, mutect2
- VSIG1 | c.1123G>C p.E375Q | Missense Mutation (SNP) | VAF 19/51 reads (37%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.055); catalogued as COSV54261543; called by muse, mutect2, varscan2
- ZBTB49 | c.1933G>A p.D645N | Missense Mutation (SNP) | VAF 10/19 reads (53%) | SIFT deleterious (0.05); PolyPhen benign (0.042); catalogued as COSV61925920; called by muse, mutect2, varscan2
- ZEB2 | c.2701C>G p.Q901E | Missense Mutation (SNP) | VAF 20/41 reads (49%) | SIFT tolerated (0.28); PolyPhen possibly damaging (0.9); catalogued as rs794727924, CM136339, COSV57964528; called by muse, mutect2, varscan2
- ZNF257 | c.1441C>T p.H481Y | Missense Mutation (SNP) | VAF 9/30 reads (30%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.542); catalogued as rs767865942, COSV71311180; called by muse, mutect2, varscan2
- ZNF354C | c.1538G>A p.R513K | Missense Mutation (SNP) | VAF 13/27 reads (48%) | SIFT tolerated (0.26); PolyPhen possibly damaging (0.508); catalogued as COSV59609508; called by muse, mutect2, varscan2
- ZNF430 | c.1151G>A p.R384Q | Missense Mutation (SNP) | VAF 22/38 reads (58%) | SIFT tolerated (0.99); PolyPhen benign (0.005); catalogued as rs199515644, COSV55109496; called by muse, mutect2, varscan2
- ZNF473 | c.2444C>T p.S815F | Missense Mutation (SNP) | VAF 9/43 reads (21%) | SIFT deleterious (0.04); PolyPhen benign (0.226); catalogued as COSV54524699; called by muse, mutect2, varscan2
- ZNF586 | c.52G>A p.E18K | Missense Mutation (SNP) | VAF 87/264 reads (33%) | SIFT deleterious (0); PolyPhen benign (0.048); catalogued as rs1361676349, COSV66972703; called by muse, mutect2, varscan2
- ZNF669 | c.109G>C p.E37Q | Missense Mutation (SNP) | VAF 12/70 reads (17%) | SIFT tolerated, low confidence (0.27); PolyPhen benign (0); catalogued as COSV58539017; called by muse, mutect2, varscan2
- ZNF750 | c.407C>A p.S136* | Nonsense Mutation (SNP) | VAF 26/79 reads (33%) | catalogued as COSV53962334; called by muse, mutect2, varscan2
- TAF15 | c.1510G>C p.D504H (on ENST00000605844 / NM_139215.3; = p.D501H on NM_003487.4) | Missense Mutation (SNP) | VAF 43/120 reads (36%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.907); called by muse, mutect2, varscan2
- ABCA13 | c.2994C>T p.I998= | Silent (SNP) | VAF 10/28 reads (36%) | catalogued as COSV70041488; called by muse, mutect2, varscan2
- ABCG5 | c.741C>G p.L247= | Silent (SNP) | VAF 18/58 reads (31%) | catalogued as rs769339847, COSV53212972, COSV53213577; called by muse, mutect2, varscan2
- ADSL | c.264G>A p.V88= | Silent (SNP) | VAF 11/36 reads (31%) | catalogued as COSV53409644; called by muse, mutect2, varscan2
- ALOX15B | c.159C>T p.F53= | Silent (SNP) | VAF 19/43 reads (44%) | catalogued as COSV66479314; called by muse, mutect2, varscan2
- AMOTL2 | c.1131G>A p.R377= | Silent (SNP) | VAF 12/30 reads (40%) | catalogued as COSV51440483; called by muse, mutect2, varscan2
- CCIN | c.552C>G p.L184= | Silent (SNP) | VAF 39/63 reads (62%) | catalogued as COSV58725337, COSV58726020; called by muse, mutect2, varscan2
- CDKN2AIP | c.1596G>A p.L532= | Silent (SNP) | VAF 6/12 reads (50%) | catalogued as COSV56627946; called by muse, mutect2, varscan2
- CPVL | c.660C>G p.L220= | Silent (SNP) | VAF 14/43 reads (33%) | catalogued as COSV55307272; called by muse, mutect2, varscan2
- CRYBG3 | c.8319G>C p.V2773= | Silent (SNP) | VAF 19/34 reads (56%) | catalogued as COSV51715214; called by muse, mutect2, varscan2
- DENND2B | c.2904G>C p.L968= | Silent (SNP) | VAF 13/26 reads (50%) | catalogued as rs750902969, COSV58206068, COSV58206986; called by muse, mutect2, varscan2
- EMC1 | c.2466C>T p.F822= | Silent (SNP) | VAF 8/58 reads (14%) | catalogued as COSV100916454; called by muse, mutect2, varscan2
- EPHB4 | c.1530C>T p.R510= | Silent (SNP) | VAF 25/59 reads (42%) | catalogued as COSV62269244; called by muse, mutect2, varscan2
- GAS2L2 | c.2127G>C p.L709= | Silent (SNP) | VAF 6/36 reads (17%) | called by muse, mutect2, varscan2
- GNPTG | c.813G>T p.T271= | Silent (SNP) | VAF 8/24 reads (33%) | catalogued as COSV50190690; called by muse, mutect2, varscan2
- GPRC5A | c.639C>T p.I213= | Silent (SNP) | VAF 75/125 reads (60%) | catalogued as COSV50008528; called by muse, mutect2, varscan2
- HVCN1 | c.288C>T p.F96= | Silent (SNP) | VAF 62/112 reads (55%) | catalogued as rs751172130, COSV99657243; called by muse, mutect2, varscan2
- IER5L | c.1182C>T p.L394= | Silent (SNP) | VAF 3/10 reads (30%) | catalogued as rs748078472, COSV65262863; called by muse, mutect2
- IGSF9B | c.1332C>T p.A444= | Silent (SNP) | VAF 19/39 reads (49%) | catalogued as rs780312740, COSV58071657, COSV58074263; called by muse, mutect2, varscan2
- KIF13B | c.2955G>A p.V985= | Silent (SNP) | VAF 9/30 reads (30%) | catalogued as rs1230128681, COSV72954637; called by muse, mutect2, varscan2
- MAP3K9 | c.648C>G p.L216= | Silent (SNP) | VAF 35/55 reads (64%) | catalogued as COSV67122594, COSV67123248; called by muse, mutect2, varscan2
- MAPK9 | c.477G>A p.V159= | Silent (SNP) | VAF 17/33 reads (52%) | catalogued as COSV58124872; called by muse, mutect2, varscan2
- MROH2B | c.2617C>T p.L873= | Silent (SNP) | VAF 20/47 reads (43%) | catalogued as COSV68188391; called by muse, mutect2, varscan2
- MUC16 | c.16413C>T p.I5471= | Silent (SNP) | VAF 24/81 reads (30%) | catalogued as COSV67486997; called by muse, mutect2, varscan2
- NIPAL3 | c.391C>T p.L131= | Silent (SNP) | VAF 54/69 reads (78%) | catalogued as COSV50235853; called by muse, mutect2, varscan2
- PCDHB7 | c.1410C>T p.I470= | Silent (SNP) | VAF 80/171 reads (47%) | catalogued as COSV50783457, COSV50805197; called by muse, mutect2
- PCNX3 | c.3444C>T p.L1148= | Silent (SNP) | VAF 15/50 reads (30%) | catalogued as rs769292775, COSV63139846; called by muse, mutect2, varscan2
- PILRB | c.441C>G p.L147= | Silent (SNP) | VAF 11/32 reads (34%) | catalogued as COSV60335972; called by muse, mutect2, varscan2
- PRDX5 | c.606C>T p.L202= | Silent (SNP) | VAF 24/63 reads (38%) | catalogued as COSV50007899; called by muse, mutect2, varscan2
- PTPRJ | c.3849G>A p.Q1283= | Silent (SNP) | VAF 18/45 reads (40%) | catalogued as COSV69254072; called by muse, mutect2, varscan2
- RPL8 | c.657C>T p.I219= | Silent (SNP) | VAF 13/30 reads (43%) | catalogued as rs746835373, COSV52799781; called by muse, mutect2, varscan2
- RYR1 | c.1461G>C p.L487= | Silent (SNP) | VAF 72/128 reads (56%) | catalogued as COSV62107566; called by muse, mutect2, varscan2
- SLC25A30 | c.546C>G p.V182= | Silent (SNP) | VAF 12/35 reads (34%) | catalogued as COSV60434409; called by muse, mutect2, varscan2
- SLC39A14 | c.198C>G p.L66= | Silent (SNP) | VAF 17/38 reads (45%) | catalogued as COSV51486631; called by muse, mutect2, varscan2
- SNN | c.123C>T p.I41= | Silent (SNP) | VAF 8/27 reads (30%) | catalogued as rs376162683; called by muse, mutect2, varscan2
- SOS2 | c.2940G>C p.R980= | Silent (SNP) | VAF 10/24 reads (42%) | catalogued as COSV53572874; called by muse, mutect2, varscan2
- TECPR1 | c.2796C>T p.I932= | Silent (SNP) | VAF 25/46 reads (54%) | catalogued as rs188761694, COSV65782923; called by muse, mutect2, varscan2
- TET1 | c.4506C>T p.V1502= | Silent (SNP) | VAF 13/27 reads (48%) | catalogued as COSV65388509; called by muse, mutect2, varscan2
- TEX29 | c.54C>T p.F18= | Silent (SNP) | VAF 10/18 reads (56%) | catalogued as COSV52096378; called by muse, mutect2, varscan2
- TGOLN2 | c.30G>A p.L10= | Silent (SNP) | VAF 48/102 reads (47%) | catalogued as COSV56407285, COSV56407847; called by muse, varscan2
- TMEM175 | c.873G>T p.V291= | Silent (SNP) | VAF 5/14 reads (36%) | catalogued as COSV99297879; called by muse, mutect2, varscan2
- UBE2H | c.262C>T p.L88= | Silent (SNP) | VAF 16/30 reads (53%) | catalogued as COSV62921576; called by muse, mutect2, varscan2
- VEGFB | c.259C>T p.L87= | Silent (SNP) | VAF 13/36 reads (36%) | catalogued as COSV58538262; called by muse, mutect2, varscan2
- ZBTB38 | c.3261C>T p.I1087= | Silent (SNP) | VAF 15/35 reads (43%) | catalogued as COSV58543768; called by muse, mutect2, varscan2
- ZNF184 | c.2064T>C p.H688= | Silent (SNP) | VAF 24/63 reads (38%) | catalogued as COSV53005336; called by muse, mutect2, varscan2
- ZNF473 | c.2217C>T p.F739= | Silent (SNP) | VAF 14/46 reads (30%) | catalogued as rs779467075, COSV54524126; called by muse, mutect2, varscan2
- ZNF501 | c.291G>C p.L97= | Silent (SNP) | VAF 6/17 reads (35%) | catalogued as rs1263061516, COSV68516600; called by muse, mutect2, varscan2
- CES2 | c.-9G>C | 5'UTR (SNP) | VAF 24/97 reads (25%) | catalogued as rs773056840, COSV57697592; called by muse, mutect2, varscan2
- CLN5 | c.*52G>C | 3'UTR (SNP) | VAF 9/20 reads (45%) | catalogued as CM026023, COSV62919239; called by muse, mutect2, varscan2
- MCF2L | c.368+2187G>A | Intron (SNP) | VAF 21/80 reads (26%) | catalogued as rs752725748, COSV65052949; called by muse, mutect2, varscan2
- SALL2 | c.74-446C>T | Intron (SNP) | VAF 5/23 reads (22%) | catalogued as rs756161283, COSV58105357; called by muse, mutect2
- SYTL2 | c.1460-3163G>A | Intron (SNP) | VAF 27/72 reads (38%) | catalogued as COSV60362482; called by muse, mutect2, varscan2
- XIST | n.8150C>G | RNA (SNP) | VAF 18/47 reads (38%) | called by muse, mutect2, varscan2
